Surgical pathology report (de-identified scan), TCGA case TCGA-61-2613, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2613-01A (Primary Tumor).

FINAL DIAGNOSIS:

FINAL DIAGNOSIS:

INTRA-ABDOMINAL WALL NODE:

- METASTATIC ADENOCARCINOMA

B) OMENTAL NODULE:

- METASTATIC ADENOCARCINOMA

C) RIGHT ADNEXA:

- MODERATELY DIFFERENTIATED SEROUS PAPILLARY ADENOCARCINOMA OF RIGHT OVARY

- UNREMARKABLE FALLOPIAN TUBE

D) FUNDUS OF UTERUS:

- ATROPHIC ENDOMETRIUM

- UNREMARKABLE MYOMETRIUM

- SEROUS PAPILLARY ADENOCARCINOMA INVOLVING SEROSA

E) LEFT ADNEXA:

- MODERATELY DIFFERENTIATED SEROUS PAPILLARY ADENOCARCINOMA OF LEFT OVARY

- UNREMARKABLE FALLOPIAN TUBE

Source: NCI Genomic Data Commons file 8495c41c-e717-46cf-87b0-45e0c8c4a7d0 (TCGA-61-2613.6D7A40B1-02F0-4D7E-B3E2-E467E404A241.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).